Somatic mutation profile of tumor specimen TCGA-DJ-A3V3-01A (aliquot TCGA-DJ-A3V3-01A-11D-A22Z-08) from TCGA case TCGA-DJ-A3V3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 57.5 years (20,997 days).
Specimen TCGA-DJ-A3V3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3225acf9-48d6-4404-ab36-ca23fbf21444.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V3-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V3-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04827ac-6646-464f-b6bf-1179a6c89ea1

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP9 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99583094; called by muse, mutect2, varscan2
- LEPR | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100756693; called by muse, mutect2, varscan2
- OR1L8 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201342990, COSV100508618; called by muse, mutect2, varscan2
- GPR132 | c.78G>A p.L26= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100317665; called by muse, mutect2, varscan2
